Somatic mutation profile of tumor specimen TARGET-10-PAPBAI-09A (aliquot TARGET-10-PAPBAI-09A-01D) from TARGET case TARGET-10-PAPBAI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (960 days).
Specimen TARGET-10-PAPBAI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d414cf8-b2ff-443e-9d28-4b912454f897.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBAI-10A (Blood Derived Normal), aliquot TARGET-10-PAPBAI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96b9d3b7-de02-45a4-b9c7-b6c673dde625

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 3'UTR 1, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 31/71 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APLP1 | c.1715C>A p.A572E (on ENST00000221891 / NM_001024807.3; = p.A571E on NM_005166.4) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1473647764; called by muse, mutect2, varscan2
- B3GALT1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59910195; called by muse, mutect2, varscan2
- CACNA1D | c.3134C>T p.T1045M (on ENST00000350061 / NM_001128840.3; = p.T1065M on NM_000720.4) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs773341387; called by muse, mutect2, varscan2
- HMCN2 | c.14510C>T p.P4837L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1329518223; called by muse, mutect2, varscan2
- VEGFC | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs554908874, COSV54594769; called by muse, mutect2
- LAMC2 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2
- MAGEC1 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEURL4 | c.4286G>A p.R1429Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PLOD2 | c.882C>T p.V294= | Splice Region (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- PPP4R4 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PTPRQ | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM50B | c.786C>T p.S262= | Silent (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- MAP3K9 | c.3258G>A p.A1086= (on ENST00000554752 / NM_001284230.1; = p.A1100= on NM_033141.4) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs149882494; called by muse, mutect2, varscan2
- ANO4 | c.-107G>A | 5'UTR (SNP) | VAF 13/34 reads (38%) | catalogued as rs780112580, COSV54620211; called by muse, mutect2, varscan2
- CXCR1 | c.*9G>A | 3'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as rs761674190, COSV99826301; called by muse, mutect2
- QRFPR | c.499+40T>A | Intron (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
